Somatic mutation profile of tumor specimen TCGA-BS-A0UJ-01A (aliquot TCGA-BS-A0UJ-01A-12D-A10B-09) from TCGA case TCGA-BS-A0UJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 68.9 years (25,149 days).
Specimen TCGA-BS-A0UJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99fb7215-3d02-4053-8876-78b0e2312f76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0UJ-10A (Blood Derived Normal), aliquot TCGA-BS-A0UJ-10A-01D-A127-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/110a19b8-50d4-4a30-b64b-1cd6b76debeb

The open-access MAF lists 1,983 somatic variants for this specimen: 1,476 protein-altering or splice-affecting, 481 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,241, Silent 481, Frame Shift Ins 89, Nonsense Mutation 64, Splice Site 47, Splice Region 23, Intron 16, Nonstop Mutation 5, 3'UTR 4, Translation Start Site 4, RNA 3, Frame Shift Del 2.

Variants (750 of 1,983; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs63750427, CM001040, CM030399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BVES | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 38/96 reads (40%) | catalogued as rs796206315, COSV58947369; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CARD11 | c.644A>C p.K215T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62717709, COSV62720893; called by muse, mutect2, varscan2
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNMT3B | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 59/107 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV52416499, COSV52423307; called by muse, mutect2, varscan2
- ERBB3 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 56/107 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519891, COSV57247504, COSV57260861, COSV57263527; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAP2K4 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 33/68 reads (49%) | hotspot (GDC flag); catalogued as rs1164096095, COSV62258353; called by muse, mutect2, varscan2
- MYH7 | c.2594A>G p.K865R | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs758891557, CM068016, COSV62522038; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 67/165 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 42/110 reads (38%) | hotspot (GDC flag); catalogued as COSV56262126; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 20/65 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 44/78 reads (56%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, varscan2
- SMPD1 | c.1264-1G>A p.X422_splice | Splice Site (SNP) | VAF 62/142 reads (44%) | catalogued as rs1057516454, COSV54969861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.1196A>C p.K399T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV62931758; called by muse, varscan2
- ABCA1 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66059438; called by muse, varscan2
- ABCA12 | c.5477T>C p.L1826S (on ENST00000272895 / NM_173076.3; = p.L1508S on NM_015657.3) | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs750268839, COSV55969688; called by muse, mutect2, varscan2
- ABCA9 | c.2601-2A>G p.X867_splice | Splice Site (SNP) | VAF 24/51 reads (47%) | catalogued as COSV60629015; called by muse, varscan2
- ABCB7 | c.425T>C p.I142T (on ENST00000373394 / NM_001271696.3; = p.I143T on NM_004299.6) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV53722379; called by muse, mutect2, varscan2
- ABCC2 | c.3787G>T p.E1263* | Nonsense Mutation (SNP) | VAF 135/328 reads (41%) | catalogued as COSV64987833, COSV64988000; called by muse, mutect2, varscan2
- ABCF1 | c.1861A>C p.S621R (on ENST00000326195 / NM_001025091.2; = p.S583R on NM_001090.3) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV58230156; called by muse, mutect2, varscan2
- ABHD5 | c.301A>G p.N101D | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50006864; called by muse, mutect2, varscan2
- ABLIM1 | c.266A>G p.H89R | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV53312309; called by muse, mutect2, varscan2
- AC090517.4 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as COSV50999152; called by muse, mutect2, varscan2
- AC131160.1 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as COSV57701681; called by muse, mutect2, varscan2
- ACACB | c.2677G>T p.D893Y | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58136511, COSV58137390; called by muse, mutect2, varscan2
- ACAT1 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV54921867; called by muse, mutect2, varscan2
- ACAT1 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54921876; called by muse, mutect2, varscan2
- ACE2 | c.2324G>T p.R775I | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV53026644; called by muse, mutect2, varscan2
- ACHE | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 30/59 reads (51%) | catalogued as COSV53820314; called by muse, mutect2, varscan2
- ACOT8 | c.155A>G p.K52R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54170585; called by muse, mutect2, varscan2
- ACOX1 | c.976A>C p.T326P | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53135133; called by muse, mutect2, varscan2
- ACP4 | c.1045A>G p.S349G | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV54518144; called by muse, mutect2, varscan2
- ACSF3 | c.1307A>G p.Y436C | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58080573; called by muse, mutect2, varscan2
- ACSM2B | c.738T>C p.A246= | Splice Region (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100312942, COSV61659223; called by muse, mutect2, varscan2
- ACSS2 | c.662A>G p.E221G | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs763870941, COSV99489469; called by muse, mutect2, varscan2
- ACVR1C | c.1402A>G p.N468D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV54648628; called by muse, mutect2, varscan2
- ACVR1C | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV54648637; called by muse, mutect2, varscan2
- ADAM28 | c.1953G>T p.W651C | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs938364573, COSV56103422; called by muse, mutect2, varscan2
- ADAMTS12 | c.3082A>G p.R1028G | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs200132406, COSV61272772; called by muse, varscan2
- ADAMTS15 | c.2161G>A p.G721R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1407524963, COSV54508433, COSV54508690; called by muse, mutect2, varscan2
- ADAMTS5 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53182931; called by muse, mutect2, varscan2
- ADAMTS9 | c.5548A>G p.S1850G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.04); catalogued as COSV55786998; called by muse, mutect2, varscan2
- ADGRA1 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV63416755; called by muse, mutect2, varscan2
- ADGRE5 | c.1723A>T p.I575F (on ENST00000242786 / NM_078481.4; = p.I482F on NM_001784.5) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54392858; called by muse, mutect2, varscan2
- ADGRG6 | c.445G>T p.V149F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51598054; called by muse, varscan2
- ADGRV1 | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1189997776, COSV67991853; called by muse, mutect2, varscan2
- ADGRV1 | c.2933T>C p.L978P | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67991856; called by muse, mutect2, varscan2
- ADGRV1 | c.11447T>C p.L3816S | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV67991865; called by muse, mutect2, varscan2
- ADGRV1 | c.17503G>T p.D5835Y | Missense Mutation (SNP) | VAF 101/200 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV67991868; called by muse, mutect2, varscan2
- AFP | c.26dup p.L9Ffs*9 | Frame Shift Ins (INS) | VAF 28/73 reads (38%) | catalogued as rs1479715998; called by mutect2, varscan2
- AFTPH | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV53220508; called by muse, mutect2, varscan2
- AGFG2 | c.414A>T p.K138N | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53546499; called by muse, mutect2, varscan2
- AGGF1 | c.947T>C p.M316T | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs372772164, COSV57230594; called by muse, mutect2, varscan2
- AGO4 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV64618102; called by muse, mutect2, varscan2
- AGPAT4 | c.1127T>G p.L376R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV57249031; called by muse, mutect2, varscan2
- AHCTF1 | c.4501A>G p.T1501A (on ENST00000366508; = p.T1475A on NM_015446.5) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs759656970, COSV58253360; called by muse, mutect2, varscan2
- AIRE | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52395769; called by muse, mutect2, varscan2
- AK9 | c.3208G>T p.E1070* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100392894; called by muse, mutect2
- AKAP11 | c.2584T>C p.S862P | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV50299517; called by muse, mutect2, varscan2
- AKAP3 | c.923T>C p.V308A | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV57419160; called by muse, mutect2, varscan2
- AKAP3 | c.476T>C p.L159S | Missense Mutation (SNP) | VAF 72/117 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV57419175; called by muse, mutect2, varscan2
- AKAP4 | c.1469T>C p.L490P | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV62075174; called by muse, mutect2, varscan2
- AKAP9 | c.1706A>G p.E569G | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs1440127984, COSV62353999; called by muse, mutect2, varscan2
- AKAP9 | c.7297A>G p.M2433V (on ENST00000359028; = p.M2409V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100661741; called by muse, mutect2
- AKAP9 | c.9793G>T p.E3265* (on ENST00000359028; = p.E3241* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV62354014; called by muse, mutect2, varscan2
- AKNAD1 | c.2138C>A p.S713Y | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV62201740; called by muse, mutect2, varscan2
- ALAS1 | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV59629066; called by muse, mutect2, varscan2
- ALB | c.1092T>A p.D364E | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55740761; called by muse, mutect2, varscan2
- ALG8 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 79/177 reads (45%) | catalogued as COSV55202054; called by muse, mutect2, varscan2
- ALMS1 | c.12359A>C p.K4120T | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV52517511; called by muse, mutect2, varscan2
- ALOX12B | c.1729A>G p.K577E | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV59875043; called by muse, mutect2, varscan2
- ALOX15 | c.1378T>C p.Y460H | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775387753, COSV53399662; called by muse, mutect2, varscan2
- ALPK2 | c.1310A>C p.Q437P | Missense Mutation (SNP) | VAF 61/97 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV64495294; called by muse, mutect2, varscan2
- ALPK2 | c.422A>T p.D141V | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV64495300; called by muse, mutect2, varscan2
- ALPK3 | c.611A>G p.K204R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV51937425; called by muse, mutect2, varscan2
- ALX1 | c.464A>G p.H155R | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV57493590; called by muse, mutect2, varscan2
- ALX4 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV61328096; called by muse, mutect2, varscan2
- AMIGO2 | c.216A>T p.R72S | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.578); catalogued as COSV56975135; called by muse, mutect2, varscan2
- AMOTL2 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs372900931; called by muse, mutect2, varscan2
- AMPD2 | c.940A>G p.N314D | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV56649700; called by muse, mutect2, varscan2
- ANK3 | c.5513A>G p.K1838R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55073089; called by muse, mutect2, varscan2
- ANK3 | c.217-2A>G p.X73_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV55073096; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.3919T>G p.F1307V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.988); catalogued as COSV51854693; called by muse, mutect2, varscan2
- ANKLE2 | c.2117A>C p.N706T | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV61710892; called by muse, mutect2, varscan2
- ANKRD17 | c.4910A>G p.N1637S | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs763017450, COSV58225379; called by muse, mutect2, varscan2
- ANKRD28 | c.2057G>A p.G686E | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs761536330, COSV67519538; called by muse, mutect2, varscan2
- ANKS1A | c.2366A>G p.H789R | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as COSV64463070; called by muse, mutect2, varscan2
- ANO10 | c.379A>C p.I127L | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as rs745311004, COSV52734694; called by muse, mutect2, varscan2
- ANPEP | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55593576; called by muse, mutect2, varscan2
- AOPEP | c.850T>C p.C284R | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52921856; called by muse, mutect2, varscan2
- AP2A1 | c.2570T>C p.L857P | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV58242478; called by muse, mutect2, varscan2
- APAF1 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 135/303 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV54490753; called by muse, mutect2, varscan2
- APC | c.2333A>G p.N778S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); catalogued as rs753274177, CD086477, CD106417, COSV57367060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC3D | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53327815; called by muse, mutect2, varscan2
- APOC1 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV52992083; called by muse, mutect2, varscan2
- APOL5 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV50767844; called by muse, mutect2, varscan2
- AQP2 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 123/292 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772051028, CM024087, COSV52229934; called by muse, mutect2, varscan2
- ARAP3 | c.4142T>C p.M1381T | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53353167; called by muse, mutect2, varscan2
- AREL1 | c.1333T>C p.F445L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV62667557; called by muse, mutect2, varscan2
- ARF6 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.503); catalogued as COSV53598077; called by muse, mutect2, varscan2
- ARFGAP1 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62262936, COSV62263705; called by muse, mutect2, varscan2
- ARHGAP5 | c.1545G>T p.M515I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.981); catalogued as COSV61538284; called by muse, varscan2
- ARHGEF12 | c.1619A>G p.K540R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV63106489; called by muse, mutect2, varscan2
- ARHGEF17 | c.5687A>G p.E1896G | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55235641; called by muse, mutect2, varscan2
- ARHGEF37 | c.1979T>C p.L660S | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61369722; called by muse, mutect2, varscan2
- ARHGEF5 | c.3620G>A p.R1207Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.313); catalogued as rs755202652, COSV50215133; called by mutect2, varscan2
- ARHGEF7 | c.1955T>C p.L652P (on ENST00000375741 / NM_001113511.2; = p.L474P on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54548478; called by muse, mutect2, varscan2
- ARID1A | c.2275A>G p.M759V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV61384748; called by muse, mutect2, varscan2
- ARID1B | c.3063A>C p.E1021D | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.437); catalogued as rs1164148507, COSV51673841; called by muse, mutect2, varscan2
- ARID5B | c.2231T>G p.M744R | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54426832; called by muse, mutect2, varscan2
- ARMCX1 | c.1134T>G p.N378K | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65705409; called by muse, mutect2, varscan2
- ASB14 | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV101274037; called by muse, mutect2, varscan2
- ASH1L | c.6425A>G p.E2142G (on ENST00000368346 / NM_001366177.2; = p.E2137G on NM_018489.3) | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); catalogued as COSV64211687; called by muse, mutect2, varscan2
- ASH1L | c.4483T>C p.S1495P | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV64211692; called by muse, mutect2, varscan2
- ASH1L | c.1125A>T p.K375N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV64211697; called by muse, mutect2, varscan2
- ASNS | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51552598; called by muse, mutect2, varscan2
- ASPM | c.8188A>C p.T2730P | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.579); catalogued as COSV54135276; called by muse, mutect2, varscan2
- ASXL2 | c.1939A>G p.T647A | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs775972387, COSV55464369; called by muse, mutect2, varscan2
- ASXL3 | c.3889C>A p.P1297T | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52474471; called by muse, mutect2, varscan2
- ATAD5 | c.622A>G p.R208G | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58977301; called by muse, mutect2, varscan2
- ATAD5 | c.3295A>G p.R1099G | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs916150523, COSV58973703, COSV58977309; called by muse, mutect2, varscan2
- ATF6B | c.1686-1G>A p.X562_splice | Splice Site (SNP) | VAF 49/97 reads (51%) | catalogued as COSV64352438; called by muse, mutect2, varscan2
- ATG16L1 | c.293A>C p.E98A | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as COSV61467170; called by muse, mutect2, varscan2
- ATM | c.8164C>A p.L2722M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV53752416, COSV53763309; called by muse, mutect2, varscan2
- ATOH1 | c.29G>T p.W10L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.699); catalogued as COSV60038442; called by muse, mutect2, varscan2
- ATP13A5 | c.3277C>A p.L1093M | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.051); catalogued as COSV60872800; called by muse, mutect2, varscan2
- ATP2B4 | c.1531A>G p.N511D | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100396904; called by muse, mutect2
- ATP6V1C2 | c.1043T>C p.F348S (on ENST00000272238 / NM_001039362.2; = p.F302S on NM_144583.4) | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs149885814; called by muse, mutect2, varscan2
- ATRX | c.1370T>A p.I457N | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.168); catalogued as COSV64880915; called by muse, mutect2, varscan2
- ATXN2L | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs751084865, COSV57376356; called by muse, mutect2, varscan2
- B3GAT2 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV57642995; called by muse, mutect2, varscan2
- B3GNT5 | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58476635; called by muse, mutect2, varscan2
- B4GALNT3 | c.1915A>G p.S639G | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV56756268; called by muse, mutect2, varscan2
- BABAM2 | c.570G>A p.K190= | Splice Region (SNP) | VAF 40/94 reads (43%) | catalogued as COSV59629816; called by muse, mutect2, varscan2
- BACE2 | c.618G>A p.K206= | Splice Region (SNP) | VAF 55/128 reads (43%) | catalogued as COSV57742009; called by muse, mutect2, varscan2
- BAG1 | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.072); catalogued as COSV65651839; called by muse, mutect2, varscan2
- BARD1 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1329558100, COSV104368786, COSV53615176; called by muse, varscan2
- BCAR1 | c.88A>G p.M30V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as COSV50794854; called by muse, mutect2, varscan2
- BCCIP | c.244T>G p.F82V | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53395786; called by muse, mutect2, varscan2
- BCL6 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV51651553, COSV51654540; called by muse, mutect2, varscan2
- BCL6 | c.906A>T p.E302D | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV51654548; called by muse, mutect2, varscan2
- BCOR | c.4367T>C p.L1456P (on ENST00000378444 / NM_001123385.2; = p.L1422P on NM_017745.6) | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60714405; called by muse, mutect2, varscan2
- BEND5 | c.1052A>G p.K351R | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV65718189; called by muse, mutect2, varscan2
- BFAR | c.838A>G p.R280G | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55494039; called by muse, mutect2, varscan2
- BIRC6 | c.6515T>C p.V2172A | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV70203699; called by muse, mutect2, varscan2
- BIRC6 | c.8482A>T p.T2828S | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV70203703; called by muse, varscan2
- BLK | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52054657; called by muse, mutect2, varscan2
- BMPR2 | c.2443A>G p.S815G | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV65812286; called by muse, mutect2, varscan2
- BOD1L1 | c.2524T>A p.S842T | Missense Mutation (SNP) | VAF 104/243 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV50007927; called by muse, mutect2, varscan2
- BPNT2 | c.1064A>G p.K355R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV52908534; called by muse, mutect2, varscan2
- BRCA1 | c.4208A>G p.N1403S | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV58796058; called by muse, mutect2, varscan2
- BRCA2 | c.7417T>C p.C2473R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs786202720, COSV66459349; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BRIP1 | c.1801T>C p.S601P | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52005439; called by muse, mutect2, varscan2
- BRWD1 | c.6860A>C p.D2287A | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV59001049; called by muse, mutect2, varscan2
- BRWD3 | c.4669G>T p.G1557* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as COSV64751940; called by muse, mutect2, varscan2
- BTAF1 | c.1753A>G p.K585E | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV56437418; called by muse, mutect2, varscan2
- BTBD11 | c.2231+1G>A p.X744_splice (on ENST00000280758 / NM_001018072.2; = p.X281_splice on NM_001017523.2) | Splice Site (SNP) | VAF 33/61 reads (54%) | catalogued as COSV55032474; called by muse, mutect2, varscan2
- BTNL3 | c.967A>G p.K323E | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61565419; called by muse, mutect2, varscan2
- C12orf50 | c.938G>T p.R313I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs541023233, COSV53894520, COSV53897632; called by muse, varscan2
- C17orf80 | c.878T>C p.M293T | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52148054; called by muse, mutect2, varscan2
- C19orf44 | c.824A>G p.Q275R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV55613866; called by muse, mutect2, varscan2
- C1QTNF2 | c.871G>A p.E291K (on ENST00000393975; = p.E246K on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as rs148128798; called by muse, mutect2, varscan2
- C1orf112 | c.1399T>G p.Y467D | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53681425; called by muse, mutect2, varscan2
- C20orf194 | c.3503A>G p.E1168G | Missense Mutation (SNP) | VAF 126/285 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV52700478; called by muse, mutect2, varscan2
- C3 | c.1706A>G p.Q569R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV55572013, COSV55578297; called by muse, mutect2, varscan2
- C4orf17 | c.463T>C p.C155R | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as rs1467075575, COSV58513262; called by muse, mutect2, varscan2
- C5orf38 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs779809202, COSV57409721; called by muse, mutect2, varscan2
- C8A | c.1013G>A p.G338D | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1409539656, COSV63483127; called by muse, mutect2, varscan2
- CAB39L | c.835-2A>G p.X279_splice | Splice Site (SNP) | VAF 34/104 reads (33%) | catalogued as COSV61716175; called by muse, varscan2
- CACNA1A | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64207017; called by muse, mutect2, varscan2
- CACNA1G | c.1319T>C p.L440P | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV61719861; called by muse, mutect2, varscan2
- CACNG3 | c.445A>G p.N149D | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV50077663; called by muse, mutect2, varscan2
- CACTIN | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV50271210, COSV99698859; called by muse, mutect2, varscan2
- CAD | c.1673T>C p.F558S | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV53030309; called by muse, mutect2, varscan2
- CALCOCO1 | c.260-2A>C p.X87_splice | Splice Site (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100017106; called by muse, mutect2, varscan2
- CALHM5 | c.684T>A p.N228K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV62068289; called by muse, mutect2, varscan2
- CAMKMT | c.685A>G p.M229V | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV65928208; called by muse, mutect2, varscan2
- CAMSAP1 | c.2942T>C p.F981S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as COSV100409474; called by muse, mutect2
- CAMSAP2 | c.987A>C p.E329D (on ENST00000236925 / NM_001297707.2; = p.E318D on NM_203459.3) | Missense Mutation (SNP) | VAF 127/273 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52675025; called by muse, mutect2, varscan2
- CAP1 | c.422T>G p.L141R | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61224120; called by muse, mutect2, varscan2
- CARNMT1 | c.1208T>C p.F403S | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65194243; called by muse, mutect2, varscan2
- CASKIN2 | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV58692460; called by muse, mutect2, varscan2
- CASP8 | c.683T>C p.M228T (on ENST00000432109 / NM_033355.3; = p.M245T on NM_001228.4) | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV51847737; called by muse, mutect2, varscan2
- CAVIN2 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV58425143; called by muse, mutect2, varscan2
- CBFA2T3 | c.544A>G p.T182A | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV51930974; called by muse, mutect2, varscan2
- CBL | c.2464A>G p.R822G | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs1487925103, COSV50651674; called by muse, mutect2, varscan2
- CC2D2A | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67505017; called by muse, mutect2, varscan2
- CCAR2 | c.2737T>C p.W913R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV52385875; called by muse, mutect2, varscan2
- CCDC136 | c.818A>G p.Q273R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV52803019; called by muse, mutect2, varscan2
- CCDC144A | c.2054T>C p.L685S | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV60700517; called by muse, mutect2, varscan2
- CCDC167 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs746959044, COSV64982729; called by muse, mutect2, varscan2
- CCDC170 | c.2123A>G p.Q708R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV99498017; called by muse, mutect2
- CCDC171 | c.2423T>C p.V808A | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV99899583; called by muse, mutect2
- CCDC173 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV69573426; called by muse, mutect2, varscan2
- CCDC18 | c.761A>C p.Q254P | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV58146251; called by muse, mutect2, varscan2
- CCDC180 | c.1151A>G p.K384R | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV63833435; called by muse, mutect2, varscan2
- CCDC191 | c.2093A>C p.Q698P | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55674861; called by muse, mutect2, varscan2
- CCDC59 | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 156/327 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV50260701; called by muse, mutect2, varscan2
- CCDC60 | c.1567A>C p.I523L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100554418; called by muse, mutect2
- CCDC61 | c.1049T>G p.F350C | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50517254; called by muse, mutect2, varscan2
- CCDC77 | c.1118A>G p.E373G | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV53474548; called by muse, mutect2, varscan2
- CCDC9B | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV101233460, COSV66875140; called by muse, mutect2, varscan2
- CCNB1IP1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 71/179 reads (40%) | catalogued as rs768364967, COSV62302820; called by muse, mutect2, varscan2
- CCNH | c.329T>C p.F110S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs758248932, COSV56925802; called by muse, mutect2, varscan2
- CCSER2 | c.261T>A p.N87K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV56509559; called by muse, mutect2, varscan2
- CCT6B | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 102/230 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV58490877; called by muse, mutect2, varscan2
- CCT8L2 | c.108C>A p.S36R | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV63463352; called by muse, mutect2, varscan2
- CD163L1 | c.3703G>A p.A1235T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.703); catalogued as COSV58021509; called by muse, mutect2, varscan2
- CD22 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs776914382, COSV50051948; called by muse, mutect2
- CD274 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as COSV67501613; called by muse, mutect2, varscan2
- CD40LG | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV65698890; called by muse, mutect2, varscan2
- CDC42BPA | c.2124A>C p.E708D | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV62017071; called by muse, mutect2, varscan2
- CDC42BPB | c.3733A>G p.T1245A | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV63476283; called by muse, mutect2, varscan2
- CDC5L | c.91T>C p.W31R | Missense Mutation (SNP) | VAF 106/269 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65176832; called by muse, mutect2, varscan2
- CDC5L | c.2081A>T p.K694M | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV65176836; called by muse, mutect2, varscan2
- CDH23 | c.2360T>C p.L787P | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54945902; called by muse, mutect2, varscan2
- CDH9 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs749126177, COSV50369544; called by muse, mutect2, varscan2
- CDHR4 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 103/214 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs903308228, COSV58526672; called by muse, mutect2, varscan2
- CDK12 | c.2030G>A p.G677D | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71002137; called by muse, mutect2, varscan2
- CDK16 | c.1259C>A p.A420D | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.308); catalogued as COSV99331370; called by muse, varscan2
- CDKAL1 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV51187816; called by muse, mutect2, varscan2
- CDKN3 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs762825170, COSV53593131; called by muse, mutect2, varscan2
- CDON | c.78C>A p.D26E | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV55000757; called by muse, mutect2, varscan2
- CEACAM20 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.306); catalogued as COSV100386742; called by muse, mutect2, varscan2
- CEMIP | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV54997705; called by muse, varscan2
- CEMIP | c.3493A>T p.K1165* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99585766; called by muse, mutect2
- CENPC | c.2227A>T p.T743S | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV56625209; called by muse, mutect2, varscan2
- CENPE | c.6811T>A p.F2271I | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1337136713, COSV54386508; called by muse, mutect2, varscan2
- CEP135 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1300495845, COSV57261913; called by muse, mutect2, varscan2
- CEP162 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 38/110 reads (35%) | catalogued as rs1427401742, COSV57622587; called by muse, mutect2, varscan2
- CEP162 | c.940A>G p.N314D | Missense Mutation (SNP) | VAF 190/444 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as COSV57622598; called by muse, mutect2, varscan2
- CEP192 | c.2317A>G p.S773G | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as COSV58068394; called by muse, mutect2, varscan2
- CEP250 | c.2094+2T>C p.X698_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV61172633; called by muse, varscan2
- CEP290 | c.5786T>C p.L1929S | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58354348; called by muse, mutect2, varscan2
- CEP83 | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT tolerated (0.98); PolyPhen benign (0.011); catalogued as COSV60410232; called by muse, varscan2
- CES1 | c.1268A>G p.D423G (on ENST00000361503 / NM_001025194.2; = p.D422G on NM_001266.5) | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62089088; called by muse, mutect2, varscan2
- CFAP161 | c.485T>C p.L162S | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746363584, COSV54430008; called by muse, mutect2, varscan2
- CFAP36 | c.656T>C p.F219S | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0.236); catalogued as COSV99701188; called by muse, mutect2
- CFAP43 | c.4031C>A p.A1344D | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs779066997, COSV63852055, COSV63854434; called by muse, mutect2, varscan2
- CFAP44 | c.1120A>C p.M374L | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55610863, COSV55614430; called by muse, mutect2, varscan2
- CFAP45 | c.31T>C p.S11P | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as rs774749136, COSV63650272; called by muse, mutect2, varscan2
- CFAP65 | c.1879T>C p.Y627H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV58564526; called by muse, mutect2, varscan2
- CFAP74 | c.2000A>G p.Q667R | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.042); catalogued as COSV54566328, COSV54571722; called by muse, mutect2, varscan2
- CGN | c.2402G>T p.R801L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs149778114, COSV54972344; called by muse, mutect2, varscan2
- CHD3 | c.2924A>G p.N975S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV57878454; called by muse, mutect2, varscan2
- CHD3 | c.3367A>G p.N1123D | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57878458; called by muse, mutect2, varscan2
- CHD6 | c.7864A>G p.I2622V | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV64693169; called by muse, mutect2, varscan2
- CHD7 | c.5632G>A p.D1878N | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV71113280; called by muse, mutect2, varscan2
- CHD8 | c.4403G>A p.G1468E (on ENST00000646647 / NM_001170629.2; = p.G1189E on NM_020920.4) | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1422490949, COSV63219462; called by muse, mutect2, varscan2
- CHD8 | c.3804T>A p.F1268L (on ENST00000646647 / NM_001170629.2; = p.F989L on NM_020920.4) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.488); catalogued as COSV67872044; called by muse, mutect2, varscan2
- CHKA | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55841341; called by muse, mutect2, varscan2
- CHL1 | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56601048; called by muse, mutect2, varscan2
- CHP1 | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58158030; called by muse, mutect2, varscan2
- CHRM4 | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.013); catalogued as COSV63127122; called by muse, mutect2, varscan2
- CHRNA10 | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV51710041; called by muse, mutect2, varscan2
- CHST1 | c.863T>C p.M288T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57324949; called by muse, mutect2, varscan2
- CIB4 | c.330T>A p.D110E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99994511; called by muse, mutect2, varscan2
- CKAP5 | c.154T>A p.L52M | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56371888; called by muse, mutect2, varscan2
- CLCA2 | c.2807A>G p.K936R | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV65288162; called by muse, mutect2, varscan2
- CLCN6 | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.721); catalogued as rs745893586, COSV100411854, COSV56742154, COSV56743438; called by muse, mutect2, varscan2
- CLEC9A | c.376T>G p.Y126D | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV63351229; called by muse, mutect2, varscan2
- CLIC2 | c.266T>C p.F89S | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58937972; called by muse, mutect2, varscan2
- CLIP4 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV60751133; called by muse, mutect2, varscan2
- CLMP | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.157); catalogued as COSV71650399; called by muse, mutect2, varscan2
- CLOCK | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767225278, COSV59401178; called by muse, mutect2, varscan2
- CLPX | c.1863A>C p.E621D | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV55645876; called by muse, mutect2, varscan2
- CLSPN | c.3883G>A p.A1295T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.2); catalogued as COSV52055237; called by muse, mutect2, varscan2
- CLVS2 | c.128A>C p.D43A | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51567093; called by muse, mutect2, varscan2
- CMYA5 | c.4692G>T p.E1564D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV71408349; called by muse, mutect2, varscan2
- CNKSR2 | c.2409G>T p.E803D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV54262764; called by muse, mutect2, varscan2
- CNN2 | c.271T>C p.F91L | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV54047809; called by muse, mutect2, varscan2
- CNOT1 | c.3980A>G p.E1327G | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV99798930; called by muse, mutect2
- CNOT1 | c.221T>G p.L74R | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV57776877, COSV57777702; called by muse, mutect2, varscan2
- CNTN1 | c.1726A>G p.K576E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV61643401; called by muse, mutect2, varscan2
- CNTRL | c.5487G>T p.L1829F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV53051154, COSV53051205; called by muse, mutect2, varscan2
- CNTROB | c.1694A>G p.N565S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1194565766, COSV66608973; called by muse, mutect2, varscan2
- COBLL1 | c.2401T>C p.Y801H (on ENST00000392717; = p.Y763H on NM_014900.5) | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52073512; called by muse, varscan2
- COG7 | c.1293-2A>G p.X431_splice | Splice Site (SNP) | VAF 52/123 reads (42%) | catalogued as COSV56152044; called by muse, mutect2, varscan2
- COL16A1 | c.72A>G p.T24= | Splice Region (SNP) | VAF 46/101 reads (46%) | catalogued as rs752933855, COSV54711305; called by muse, mutect2, varscan2
- COL19A1 | c.3049G>T p.E1017* | Nonsense Mutation (SNP) | VAF 46/108 reads (43%) | catalogued as COSV59574947; called by muse, mutect2, varscan2
- COL4A3 | c.4551T>G p.N1517K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67418249; called by muse, mutect2, varscan2
- COL4A4 | c.5041A>C p.S1681R | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61634820; called by muse, mutect2, varscan2
- COL4A4 | c.530T>C p.F177S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.368); catalogued as COSV61634822; called by muse, mutect2, varscan2
- COL4A6 | c.2914G>T p.G972C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57873550; called by muse, mutect2, varscan2
- COL5A1 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.987); catalogued as rs759839246, COSV65672974; called by muse, mutect2, varscan2
- COL5A1 | c.5020A>G p.T1674A | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV65672977; called by muse, mutect2, varscan2
- COL5A2 | c.1260T>C p.G420= | Splice Region (SNP) | VAF 14/50 reads (28%) | catalogued as COSV66412754; called by muse, varscan2
- COL6A3 | c.8476T>C p.F2826L | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1416927192, COSV55101577; called by muse, mutect2, varscan2
- COMMD4 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51190935; called by muse, mutect2, varscan2
- COPS2 | c.1236T>A p.D412E | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV54646932; called by muse, mutect2, varscan2
- COPS2 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54646942; called by muse, mutect2, varscan2
- COPS3 | c.1169T>C p.L390P | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52006735; called by muse, mutect2, varscan2
- COPS5 | c.367A>G p.N123D | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.158); catalogued as COSV100769845; called by muse, mutect2
- CORO1C | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV54598123; called by muse, mutect2, varscan2
- CPLX4 | c.158T>G p.I53S | Missense Mutation (SNP) | VAF 110/228 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV100231578, COSV55314406; called by muse, mutect2, varscan2
- CPNE9 | c.1486T>G p.F496V | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV56069365; called by muse, mutect2, varscan2
- CPT1B | c.2029-2A>G p.X677_splice | Splice Site (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100376423; called by muse, mutect2
- CR1L | c.185A>C p.N62T | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV54329590; called by muse, mutect2, varscan2
- CREB1 | c.663T>G p.I221M (on ENST00000432329 / NM_134442.5; = p.I207M on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62066094; called by muse, mutect2, varscan2
- CRY1 | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV50487716, COSV50488208; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1220A>G p.Q407R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs913439048, COSV59981480; called by muse, mutect2, varscan2
- CSMD3 | c.8440+2T>C p.X2814_splice (on ENST00000297405 / NM_001363185.1; = p.X2645_splice on NM_052900.3) | Splice Site (SNP) | VAF 34/84 reads (40%) | catalogued as COSV52266998; called by muse, mutect2, varscan2
- CSMD3 | c.6922G>T p.D2308Y (on ENST00000297405 / NM_001363185.1; = p.D2204Y on NM_052900.3) | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52267019; called by muse, mutect2, varscan2
- CSMD3 | c.3522C>A p.F1174L (on ENST00000297405 / NM_001363185.1; = p.F1070L on NM_052900.3) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs756399245, COSV99820116; called by muse, mutect2
- CSMD3 | c.1253A>G p.H418R | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV52267039; called by muse, mutect2, varscan2
- CSPG4 | c.6209C>T p.A2070V | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57899483; called by muse, mutect2, varscan2
- CTCF | c.619A>C p.T207P | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV50495328; called by muse, mutect2, varscan2
- CTNNA1 | c.1880A>G p.K627R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57078885; called by muse, mutect2, varscan2
- CTNND2 | c.3580A>G p.T1194A | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV58911769; called by muse, mutect2, varscan2
- CTPS2 | c.1361G>T p.R454I | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV63723592; called by muse, mutect2, varscan2
- CTXN3 | c.89C>A p.T30K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV65218684; called by muse, mutect2, varscan2
- CUL1 | c.1699A>G p.T567A | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.347); catalogued as COSV57391192; called by muse, mutect2, varscan2
- CUL3 | c.116dup p.N39Kfs*9 | Frame Shift Ins (INS) | VAF 44/127 reads (35%) | catalogued as rs1553535855; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- CXCR2 | c.787T>C p.C263R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59281609; called by muse, mutect2, varscan2
- CYB561D1 | c.430T>C p.C144R | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV60205649; called by muse, mutect2, varscan2
- CYB5R3 | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61546238; called by muse, mutect2, varscan2
- CYBC1 | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs765856193, COSV60065283; called by muse, mutect2, varscan2
- CYLC2 | c.300A>C p.K100N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs753500877, COSV66338828; called by muse, mutect2, varscan2
- CYP17A1 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV64005063; called by muse, mutect2, varscan2
- CYP1A2 | c.1166+2T>C p.X389_splice | Splice Site (SNP) | VAF 54/114 reads (47%) | catalogued as COSV59660472; called by muse, mutect2, varscan2
- CYP2C18 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 53/113 reads (47%) | catalogued as rs1484221641, COSV53672088; called by muse, mutect2, varscan2
- CYP4X1 | c.400T>G p.F134V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV64151405; called by muse, mutect2, varscan2
- CYTH3 | c.449+1G>A p.X150_splice | Splice Site (SNP) | VAF 83/166 reads (50%) | catalogued as COSV63440360; called by muse, mutect2, varscan2
- CYYR1 | c.382T>A p.L128M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54834792, COSV54835659; called by muse, mutect2, varscan2
- DAAM2 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51380247; called by muse, mutect2, varscan2
- DBNDD2 | c.360C>A p.F120L | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1267760743, COSV100619556, COSV61918951; called by muse, mutect2, varscan2
- DCAF10 | c.1169T>C p.V390A | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV54289942; called by muse, mutect2, varscan2
- DCAF6 | c.2398A>G p.K800E (on ENST00000312263 / NM_001349778.1; = p.K820E on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.063); catalogued as COSV56582601; called by muse, mutect2, varscan2
- DCDC1 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.439); catalogued as COSV100663951, COSV60852903; called by muse, mutect2, varscan2
- DCN | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV50008310; called by muse, mutect2, varscan2
- DCT | c.316T>C p.C106R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1312418344, COSV65470322; called by muse, varscan2
- DDX1 | c.1879T>C p.W627R | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV51842145; called by muse, mutect2, varscan2
- DDX17 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.13); catalogued as COSV53249202, COSV99318460; called by muse, mutect2, varscan2
- DDX27 | c.1789C>T p.L597F | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV100873451, COSV65609734; called by muse, mutect2, varscan2
- DDX50 | c.2159G>T p.R720L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.931); catalogued as COSV65293059; called by muse, mutect2, varscan2
- DDX51 | c.1858A>G p.M620V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs1259680801, COSV57959381; called by muse, mutect2, varscan2
- DDX60 | c.2512A>G p.S838G | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV67098310; called by muse, mutect2, varscan2
- DENND4A | c.2525A>G p.D842G | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as COSV71266714; called by muse, mutect2, varscan2
- DENND4B | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV63410945; called by muse, mutect2, varscan2
- DENND5A | c.831T>A p.N277K | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.67); PolyPhen benign (0.142); catalogued as COSV60236597; called by muse, mutect2, varscan2
- DGKD | c.1836A>T p.R612S (on ENST00000264057 / NM_152879.3; = p.R568S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51080874; called by muse, mutect2, varscan2
- DHRS2 | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as COSV51633254; called by muse, mutect2, varscan2
- DHX34 | c.3383T>C p.F1128S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV60897099; called by muse, mutect2, varscan2
- DIAPH3 | c.3042G>T p.E1014D (on ENST00000400324 / NM_001042517.2; = p.E751D on NM_030932.3) | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.664); catalogued as COSV57376800; called by muse, mutect2, varscan2
- DIAPH3 | c.973dup p.C325Lfs*29 (on ENST00000400324 / NM_001042517.2; = p.C62Lfs*29 on NM_030932.3) | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs766969544; called by mutect2, varscan2
- DIDO1 | c.25A>G p.N9D | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV56630589; called by muse, mutect2, varscan2
- DIP2A | c.1917C>A p.N639K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59483625; called by muse, mutect2, varscan2
- DISP3 | c.2024T>C p.V675A | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV99606949; called by muse, mutect2
- DKC1 | c.823A>T p.N275Y | Missense Mutation (SNP) | VAF 11/276 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV101059852; called by muse, mutect2
- DLEC1 | c.3521T>C p.M1174T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs377030183; called by muse, mutect2, varscan2
- DMBT1 | c.6442T>C p.F2148L (on ENST00000338354 / NM_001377530.1; = p.F1391L on NM_004406.3) | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.503); catalogued as COSV57553682; called by muse, mutect2, varscan2
- DMD | c.4280T>C p.M1427T | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63778431; called by muse, mutect2, varscan2
- DMD | c.737A>G p.E246G | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55890915; called by muse, mutect2, varscan2
- DMXL2 | c.4967C>A p.S1656Y | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV51852130; called by muse, varscan2
- DNA2 | c.920C>A p.S307Y | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64429629; called by muse, mutect2, varscan2
- DNAH10 | c.4514T>C p.L1505P (on ENST00000409039; = p.L1444P on NM_207437.3) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68998683; called by muse, mutect2, varscan2
- DNAH11 | c.4649T>C p.F1550S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253314291, COSV60971248; called by muse, varscan2
- DNAH11 | c.10745T>C p.I3582T | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs755910385, COSV60971253; called by muse, mutect2, varscan2
- DNAH17 | c.1859A>G p.K620R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101100996; called by muse, mutect2
- DNAH2 | c.4211A>G p.E1404G | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66723554; called by muse, mutect2, varscan2
- DNAH5 | c.12671T>C p.I4224T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99443023; called by muse, mutect2
- DNAH6 | c.2269A>G p.M757V | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV52875438; called by muse, mutect2, varscan2
- DNAH8 | c.10063A>G p.T3355A | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59468839; called by muse, mutect2, varscan2
- DNAJB11 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as COSV54003294, COSV99408749; called by muse, mutect2, varscan2
- DNAJC13 | c.3730T>C p.Y1244H | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV53455348; called by muse, mutect2, varscan2
- DNMT1 | c.1435T>C p.F479L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.405); catalogued as COSV61582045; called by muse, mutect2, varscan2
- DOCK11 | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV52238533; called by muse, mutect2, varscan2
- DOCK2 | c.5087G>T p.R1696L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56977328; called by muse, mutect2, varscan2
- DOP1A | c.4004A>G p.Y1335C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52714987; called by muse, mutect2, varscan2
- DOP1B | c.984dup p.E329* | Frame Shift Ins (INS) | VAF 26/75 reads (35%) | catalogued as rs1414264989; called by mutect2, varscan2
- DOP1B | c.6866A>G p.E2289G | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67690855; called by muse, mutect2, varscan2
- DPP9 | c.1402T>C p.W468R (on ENST00000598800; = p.W497R on NM_139159.5) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV53593231; called by muse, mutect2, varscan2
- DPY19L3 | c.1552A>G p.K518E | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1489581619, COSV60478961; called by muse, mutect2, varscan2
- DPY19L3 | c.1984G>T p.G662C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60478978; called by muse, mutect2, varscan2
- DPYD | c.844G>T p.G282* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as rs867770934, COSV64609148; called by muse, mutect2, varscan2
- DSCAM | c.1662G>T p.E554D | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV68032660; called by muse, mutect2, varscan2
- DSCAM | c.602A>G p.H201R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68649870; called by muse, mutect2, varscan2
- DSG2 | c.3274G>T p.E1092* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV55201471; called by muse, mutect2, varscan2
- DSG4 | c.1967A>G p.K656R | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.33); catalogued as COSV57395203; called by muse, mutect2, varscan2
- DST | c.11573A>C p.E3858A (on ENST00000361203 / NM_001374722.1; = p.E1446A on NM_015548.5) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as COSV55031334; called by muse, mutect2, varscan2
- DST | c.11139G>T p.E3713D (on ENST00000361203 / NM_001374722.1; = p.E1301D on NM_015548.5) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV55031357; called by muse, mutect2, varscan2
- DSTN | c.308dup p.L103Ffs*12 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs750962255; called by mutect2, varscan2
- DTD2 | c.334A>G p.K112E | Missense Mutation (SNP) | VAF 133/310 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1179887978, COSV60428256; called by muse, mutect2, varscan2
- DTNA | c.25G>T p.G9* | Nonsense Mutation (SNP) | VAF 64/145 reads (44%) | catalogued as COSV52017869, COSV52018329; called by muse, mutect2, varscan2
- DVL3 | c.1726A>G p.S576G | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV53049534; called by muse, varscan2
- DYNC1H1 | c.2569A>G p.I857V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV64140276; called by muse, mutect2, varscan2
- DYNC1H1 | c.2890A>C p.I964L | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV64140281; called by muse, mutect2, varscan2
- DYTN | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1266192400, COSV65970853; called by muse, mutect2, varscan2
- DZIP3 | c.881A>G p.K294R | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64313174, COSV64314129; called by muse, mutect2, varscan2
- E2F1 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV55777678; called by muse, mutect2, varscan2
- ECE1 | c.1814T>C p.V605A | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV51668617; called by muse, mutect2, varscan2
- ECHDC1 | c.795dup p.S266Ifs*36 (on ENST00000531967 / NM_001139510.1; = p.S260Ifs*36 on NM_001002030.2) | Frame Shift Ins (INS) | VAF 21/54 reads (39%) | catalogued as rs772315663; called by mutect2, pindel, varscan2
- ECHS1 | c.826A>G p.M276V | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs148875965, COSV53370144; called by muse, mutect2, varscan2
- EDA2R | c.87+2T>C p.X29_splice | Splice Site (SNP) | VAF 22/43 reads (51%) | catalogued as rs1429363015, COSV53632417; called by muse, mutect2, varscan2
- EEA1 | c.2503C>A p.Q835K | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV59288532; called by muse, mutect2, varscan2
- EFCAB13 | c.2746C>A p.L916I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.077); catalogued as COSV58951162; called by muse, mutect2, varscan2
- EFEMP1 | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.303); catalogued as COSV62617261; called by muse, mutect2, varscan2
- EFL1 | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV51608446; called by muse, mutect2, varscan2
- EFR3A | c.22T>C p.C8R | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs764647245, COSV54460592; called by muse, varscan2
- EIF2AK1 | c.592dup p.I198Nfs*4 | Frame Shift Ins (INS) | VAF 68/195 reads (35%) | catalogued as rs767715156; called by mutect2, varscan2
- EIF2B2 | c.1040A>C p.D347A | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV56721101; called by muse, mutect2, varscan2
- EIF2S2 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66621977; called by muse, mutect2, varscan2
- EIF3E | c.146A>T p.N49I | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55204941; called by muse, mutect2, varscan2
- EIF4A2 | c.967T>C p.S323P | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV56218122; called by muse, mutect2, varscan2
- EIF4B | c.327A>C p.E109D | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV50405829; called by muse, mutect2, varscan2
- EIF5 | c.58C>A p.R20S | Missense Mutation (SNP) | VAF 116/267 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV53686109, COSV53686346; called by muse, mutect2, varscan2
- ELAC1 | c.201T>G p.H67Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53996997; called by muse, mutect2, varscan2
- ELAPOR1 | c.1040A>G p.E347G | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV64040919; called by muse, mutect2, varscan2
- ELF5 | c.454T>G p.L152V (on ENST00000312319 / NM_198381.2; = p.L142V on NM_001422.4) | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.206); catalogued as COSV56629891; called by muse, mutect2, varscan2
- ELFN2 | c.2107T>C p.Y703H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.898); catalogued as COSV68745789; called by muse, mutect2, varscan2
- ELP5 | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59709083; called by muse, mutect2
- EMC3 | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.155); catalogued as COSV55279249; called by muse, mutect2, varscan2
- EMSY | c.3923A>G p.D1308G | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV58264180; called by muse, mutect2, varscan2
- ENG | c.1316A>G p.K439R | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.265); catalogued as COSV61228377; called by muse, mutect2, varscan2
- EP300 | c.6250T>G p.F2084V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV54340680; called by muse, mutect2, varscan2
- EPB41L4B | c.1292T>C p.V431A | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV65798170; called by muse, mutect2
- EPHA1 | c.2741C>T p.P914L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.575); catalogued as rs751001344, COSV51974221; called by muse, mutect2, varscan2
- EPHA4 | c.2383G>A p.A795T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56040275; called by muse, mutect2, varscan2
- EPHA5 | c.2207T>A p.I736N | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56662058; called by muse, mutect2, varscan2
- EPHB2 | c.2107G>T p.E703* (on ENST00000400191 / NM_001309193.2; = p.E704* on NM_004442.7) | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV65859999, COSV65864889; called by muse, mutect2, varscan2
- EPS8 | c.1321A>G p.M441V | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs375337854; called by muse, mutect2, varscan2
- ERAP1 | c.25T>G p.S9A | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV57090262; called by muse, mutect2, varscan2
- ERBIN | c.3934A>G p.R1312G (on ENST00000284037 / NM_001253697.2; = p.R1271G on NM_018695.4) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV52323381; called by muse, mutect2, varscan2
- ERC1 | c.97C>A p.R33S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs571730696, COSV61693366, COSV61697937; called by muse, mutect2, varscan2
- ERCC4 | c.1081dup p.M361Nfs*4 | Frame Shift Ins (INS) | VAF 21/74 reads (28%) | catalogued as rs769120755; called by mutect2, pindel
- ERCC6L2 | c.1405A>G p.K469E | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1299309630, COSV56633259; called by muse, mutect2, varscan2
- ERGIC2 | c.931T>G p.F311V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.266); catalogued as COSV64112943; called by muse, mutect2, varscan2
- ERMP1 | c.1991T>G p.L664R | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV53038698; called by muse, mutect2, varscan2
- ERN1 | c.577T>C p.Y193H | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV70503842; called by muse, mutect2, varscan2
- ESCO1 | c.1640T>C p.F547S | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52521718; called by muse, mutect2, varscan2
- ESRP2 | c.1618A>G p.K540E (on ENST00000565858 / NM_001365264.1; = p.K530E on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV52175144; called by muse, varscan2
- ETFDH | c.933T>A p.H311Q | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57015922; called by muse, mutect2, varscan2
- EVI2B | c.32T>G p.F11C | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV58364764; called by muse, varscan2
- EXD1 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as COSV59255644; called by muse, mutect2, varscan2
- EXTL1 | c.815T>C p.F272S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1346523164, COSV65338089; called by muse, mutect2, varscan2
- F8 | c.4735A>G p.K1579E | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs782725369, CM1314192, COSV64277015; called by muse, mutect2, varscan2
- FA2H | c.640A>G p.M214V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1360442083, COSV54727387; called by muse, mutect2, varscan2
- FAIM | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV58158961; called by muse, mutect2, varscan2
- FAM107B | c.74A>T p.K25I (on ENST00000378458 / NM_001320737.1; = p.K200I on NM_031453.3) | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51690214; called by muse, mutect2, varscan2
- FAM111A | c.376A>G p.M126V | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs751068455, COSV64655685; called by muse, mutect2, varscan2
- FAM135A | c.603T>G p.D201E (on ENST00000370479 / NM_001351599.1; = p.D158E on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); catalogued as COSV52056695; called by muse, mutect2, varscan2
- FAM135A | c.3615-2A>G p.X1205_splice (on ENST00000370479 / NM_001351599.1; = p.X992_splice on NM_020819.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 39/76 reads (51%) | catalogued as COSV52056705; called by muse, mutect2, varscan2
- FAM207A | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs540825858, COSV52420155; called by muse, mutect2, varscan2
- FAM3B | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV63613623; called by muse, mutect2, varscan2
- FAM71B | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV57230190; called by muse, mutect2, varscan2
- FAM83C | c.617A>G p.Q206R | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as COSV65583968; called by muse, mutect2, varscan2
- FAM9A | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 38/505 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV101121291; called by muse, mutect2
- FANCI | c.2387T>C p.M796T | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55531507; called by muse, mutect2, varscan2
- FARSA | c.899A>G p.H300R | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108551; called by muse, mutect2
- FAT1 | c.7237A>C p.K2413Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV71675361; called by muse, mutect2, varscan2
- FAT1 | c.5515G>T p.E1839* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV71675362; called by muse, mutect2, varscan2
- FAT2 | c.1915A>G p.K639E | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV55826115; called by muse, mutect2, varscan2
- FAT3 | c.5010G>T p.K1670N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99959663; called by muse, mutect2, varscan2
- FAT3 | c.10729G>T p.D3577Y | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53152958; called by muse, mutect2, varscan2
- FAT4 | c.2488A>G p.I830V | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV67895261; called by muse, mutect2, varscan2
- FAT4 | c.13580T>C p.L4527P | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV58700657; called by muse, mutect2, varscan2
- FBN1 | c.3926T>C p.M1309T | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.171); catalogued as rs992749727, COSV57325813; called by muse, mutect2, varscan2
- FBN2 | c.1670A>G p.Y557C | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); catalogued as COSV52533602; called by muse, mutect2, varscan2
- FBXO5 | c.717G>T p.M239I | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57671508; called by muse, mutect2, varscan2
- FBXO5 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV57671512; called by muse, mutect2, varscan2
- FBXO8 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.181); catalogued as COSV67031949; called by muse, mutect2, varscan2
- FBXW12 | c.1206C>A p.H402Q | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as COSV56484945; called by muse, mutect2, varscan2
- FBXW5 | c.950A>C p.Q317P | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56403745; called by muse, mutect2, varscan2
- FES | c.1318T>C p.S440P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as COSV61000117; called by muse, mutect2, varscan2
- FEV | c.319T>C p.Y107H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55387188; called by muse, mutect2, varscan2
- FGD4 | c.953A>G p.E318G | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56787641; called by muse, mutect2, varscan2
- FGD5 | c.2176A>G p.R726G | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV53248553; called by muse, mutect2, varscan2
- FGD5 | c.2971G>A p.A991T | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs539351974, COSV53248570; called by muse, mutect2, varscan2
- FICD | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV57209634; called by muse, mutect2, varscan2
- FICD | c.430A>C p.T144P | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.406); catalogued as COSV57209637; called by muse, mutect2, varscan2
- FIGNL1 | c.1217T>C p.V406A | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs1211264975; called by muse, mutect2
- FILIP1L | c.2767A>T p.T923S (on ENST00000354552 / NM_182909.3; = p.T683S on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.125); catalogued as COSV100496853, COSV58773289; called by muse, mutect2, varscan2
- FILIP1L | c.842T>C p.V281A (on ENST00000354552 / NM_182909.3; = p.V41A on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766990305, COSV58773299; called by muse, mutect2, varscan2
- FLG | c.11204A>G p.Q3735R | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs765292962, COSV64245728; called by muse, mutect2, varscan2
- FLII | c.2084A>G p.Q695R | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs148086852; called by muse, mutect2, varscan2
- FLRT1 | c.796A>C p.N266H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.839); catalogued as COSV55365010; called by muse, mutect2, varscan2
- FLT4 | c.3845A>G p.E1282G | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1000190222, COSV56109766; called by muse, mutect2
- FMR1 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54426248; called by muse, mutect2, varscan2
- FNBP4 | c.1342A>G p.R448G | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as rs890694222, COSV55450944; called by muse, mutect2, varscan2
- FNDC8 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as COSV50103146; called by muse, mutect2, varscan2
- FNIP1 | c.3019T>A p.S1007T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV57198989; called by muse, mutect2, varscan2
- FNIP2 | c.2735T>C p.L912P | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV52443647; called by muse, mutect2, varscan2
- FOXD4 | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs1457876417, COSV58701703; called by muse, mutect2, varscan2
- FOXP4 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV57222631; called by muse, mutect2, varscan2
- FREM1 | c.2155A>T p.R719W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV66527476; called by muse, mutect2, varscan2
- FREM2 | c.7840T>C p.Y2614H | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV54846360; called by muse, mutect2, varscan2
- FRMD7 | c.1818A>T p.E606D | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV53748016; called by muse, mutect2, varscan2
- FTSJ3 | c.2218A>G p.K740E | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs866311658, COSV63790876; called by muse, mutect2, varscan2
- G3BP2 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs749753720, COSV62977150; called by muse, mutect2, varscan2
- GABRA4 | c.341T>A p.I114N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV51932608; called by muse, mutect2, varscan2
- GABRG3 | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV61527548; called by muse, mutect2, varscan2
- GAK | c.772T>A p.F258I | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58507777; called by muse, varscan2
- GALC | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54328541; called by muse, mutect2, varscan2
- GALNT13 | c.1394A>G p.Q465R | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67232243; called by muse, varscan2
- GALNT16 | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61887083; called by muse, mutect2, varscan2
- GALNT18 | c.1680A>T p.G560= | Splice Region (SNP) | VAF 10/27 reads (37%) | catalogued as COSV57154288; called by muse, mutect2, varscan2
- GALNT7 | c.1438T>G p.F480V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53933371; called by muse, mutect2, varscan2
- GANAB | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV60467402; called by muse, mutect2, varscan2
- GAPVD1 | c.2998G>T p.E1000* (on ENST00000394104; = p.E1027* on NM_015635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/99 reads (42%) | catalogued as COSV52926001; called by muse, mutect2, varscan2
- GART | c.2931A>T p.K977N | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV67819303; called by muse, mutect2, varscan2
- GBE1 | c.1831A>G p.N611D | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV70101680; called by muse, mutect2, varscan2
- GBP5 | c.626-2A>C p.X209_splice | Splice Site (SNP) | VAF 45/97 reads (46%) | catalogued as COSV100600191, COSV58593866; called by muse, mutect2, varscan2
- GBP5 | c.430A>G p.N144D | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV58593875; called by muse, mutect2, varscan2
- GBP7 | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as COSV54011023; called by muse, mutect2, varscan2
- GCM2 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65276250; called by muse, mutect2, varscan2
- GCN1 | c.319A>C p.K107Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV56112585; called by muse, mutect2, varscan2
- GDF11 | c.622A>G p.T208A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV57690363; called by muse, mutect2, varscan2
- GDPD3 | c.776T>G p.M259R | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV62391383; called by muse, mutect2, varscan2
- GLI2 | c.583A>G p.M195V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.07); catalogued as COSV58048032; called by muse, mutect2
- GNA12 | c.823A>G p.N275D | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV51744161; called by muse, mutect2, varscan2
- GNE | c.1861T>G p.Y621D (on ENST00000396594 / NM_001128227.3; = p.Y590D on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV64952606; called by muse, mutect2, varscan2
- GNL3L | c.631A>G p.N211D | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60577271; called by muse, mutect2, varscan2
- GNPTAB | c.3734T>A p.I1245K | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.079); catalogued as COSV73418390; called by muse, mutect2, varscan2
- GNPTAB | c.934-2A>G p.X312_splice | Splice Site (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100171486; called by muse, varscan2
- GOLGA1 | c.1952T>G p.L651R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52347223; called by muse, mutect2, varscan2
- GOLGA4 | c.4700A>G p.Q1567R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62710152; called by muse, mutect2, varscan2
- GORASP1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs750666409, COSV100073156, COSV57183916; called by muse, mutect2, varscan2
- GPAT3 | c.898A>T p.I300F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100022617; called by muse, mutect2, varscan2
- GPR108 | c.1445A>G p.E482G (on ENST00000264080 / NM_001080452.1; = p.E240G on NM_020171.2) | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51186397; called by muse, mutect2, varscan2
- GPR137 | c.25G>T p.V9L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV57403312; called by muse, mutect2, varscan2
- GPX5 | c.544A>G p.N182D | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69079752; called by muse, mutect2, varscan2
- GPX7 | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs1241436740, COSV63652808; called by muse, mutect2, varscan2
- GRIK4 | c.1243A>G p.N415D | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV70805317; called by muse, mutect2, varscan2
- GRIN2B | c.4415A>G p.H1472R | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV74207075; called by muse, mutect2, varscan2
- GSAP | c.1761T>G p.N587K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57532139; called by muse, mutect2, varscan2
- GSTCD | c.503A>G p.Q168R (on ENST00000360505 / NM_001031720.3; = p.Q81R on NM_024751.3) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64734879; called by muse, mutect2, varscan2
- GSTZ1 | c.440A>G p.Q147R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1256858621, COSV53624130; called by muse, mutect2, varscan2
- GTF2H1 | c.608-2A>G p.X203_splice | Splice Site (SNP) | VAF 41/82 reads (50%) | catalogued as rs756535009, COSV56379588; called by muse, mutect2, varscan2
- GUCY2F | c.1215A>T p.E405D | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV54306375; called by muse, mutect2, varscan2
- GYG2 | c.607T>C p.F203L | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV58551109; called by muse, mutect2, varscan2
- HACD1 | c.605+1G>A p.X202_splice | Splice Site (SNP) | VAF 21/64 reads (33%) | catalogued as COSV63516889; called by muse, mutect2, varscan2
- HACE1 | c.2070T>A p.N690K | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99493138; called by muse, mutect2, varscan2
- HAUS1 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56363862, COSV99959609; called by muse, mutect2, varscan2
- HAUS3 | c.1764G>T p.E588D | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV54723682; called by muse, mutect2, varscan2
- HBS1L | c.2053T>G p.*685Gext*14 | Nonstop Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV63202314; called by muse, varscan2
- HCFC1 | c.1444+2T>C p.X482_splice | Splice Site (SNP) | VAF 43/88 reads (49%) | catalogued as COSV60075701; called by muse, mutect2, varscan2
- HDDC3 | c.304A>G p.R102G | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV57746551; called by muse, mutect2, varscan2
- HDLBP | c.2153A>G p.H718R | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV60499401; called by muse, mutect2, varscan2
- HEATR1 | c.3661A>G p.R1221G | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV63982452; called by muse, mutect2, varscan2
- HEATR6 | c.875A>C p.Q292P | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV51746412, COSV51747767; called by muse, varscan2
- HECW1 | c.3487T>A p.L1163M | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV67836706; called by muse, mutect2, varscan2
- HEPH | c.2636C>T p.S879F (on ENST00000343002; = p.S612F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV57962906, COSV57966144; called by muse, mutect2, varscan2
- HERC1 | c.4579G>A p.A1527T | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs748070202, COSV71249485; called by muse, mutect2, varscan2
- HERC2 | c.2927C>T p.A976V | Missense Mutation (SNP) | VAF 157/318 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs754896051, COSV55341232; called by muse, mutect2, varscan2
- HESX1 | c.526A>G p.K176E | Missense Mutation (SNP) | VAF 91/166 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV55843081, COSV55843318; called by muse, mutect2, varscan2
- HHLA2 | c.812T>C p.L271P | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1305497864, COSV63319017; called by muse, mutect2, varscan2
- HIF1AN | c.367A>G p.M123V | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.21); catalogued as COSV54501529; called by muse, mutect2, varscan2
- HINT3 | c.547T>C p.*183Rext*72 | Nonstop Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as COSV57650378; called by muse, mutect2, varscan2
- HIVEP1 | c.4504A>G p.N1502D | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV65103885; called by muse, mutect2, varscan2
- HIVEP2 | c.4387G>T p.E1463* | Nonsense Mutation (SNP) | VAF 104/231 reads (45%) | catalogued as COSV50035417; called by muse, mutect2, varscan2
- HIVEP2 | c.691A>C p.N231H | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50035529; called by muse, mutect2, varscan2
- HLCS | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV60796466; called by muse, mutect2, varscan2
- HMCN1 | c.15630A>G p.I5210M | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV54925908; called by muse, mutect2, varscan2
- HNF1A | c.1054T>C p.S352P | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as CD121655, COSV99981811; called by muse, mutect2, varscan2
- HNRNPL | c.871A>T p.S291C | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV55494529; called by muse, mutect2, varscan2
- HORMAD2 | c.290G>T p.R97I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV60898380, COSV60900100; called by muse, mutect2, varscan2
- HOXA1 | c.947C>A p.S316Y | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV58030814; called by muse, mutect2, varscan2
- HPS3 | c.2387A>G p.Q796R | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV56056410; called by muse, varscan2
- HSPA12A | c.1352T>G p.L451R | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV65021163, COSV65023407; called by muse, mutect2, varscan2
- HSPA13 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.193); catalogued as rs556896876, COSV53466009; called by muse, mutect2, varscan2
- HSPA6 | c.1612G>A p.V538M | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.224); catalogued as COSV59062103; called by muse, mutect2, varscan2
- HSPA8 | c.277A>G p.M93V | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1283020583, COSV57085283; called by muse, mutect2, varscan2
- HSPBAP1 | c.1370A>C p.Q457P | Missense Mutation (SNP) | VAF 97/211 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs377054072, COSV60243264; called by muse, mutect2, varscan2
- HTR1D | c.410A>C p.Y137S | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58448764; called by muse, mutect2, varscan2
- HTR2C | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV52220085; called by muse, varscan2
- HTRA3 | c.1161T>G p.Y387* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV56470626, COSV56471372, COSV56472380; called by muse, mutect2, varscan2
- HUS1 | c.592T>A p.L198I | Missense Mutation (SNP) | VAF 117/272 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV51840173; called by muse, mutect2, varscan2
- HUWE1 | c.10861A>G p.K3621E | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV53358115; called by muse, mutect2, varscan2
- HUWE1 | c.2970A>G p.S990= | Splice Region (SNP) | VAF 43/114 reads (38%) | catalogued as COSV53358166; called by muse, mutect2, varscan2
- IFIT3 | c.1306A>G p.K436E | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51080113; called by muse, mutect2, varscan2
- IFNA8 | c.569G>T p.*190Lext*80 | Nonstop Mutation (SNP) | VAF 29/83 reads (35%) | catalogued as COSV66504448, COSV66504820; called by muse, mutect2, varscan2
- IFNAR1 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54253622; called by muse, mutect2, varscan2
- IFNAR2 | c.1548A>G p.*516Wext*5 | Nonstop Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV51617090; called by muse, mutect2, varscan2
- IFT140 | c.2162T>C p.L721P | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68493273; called by muse, mutect2, varscan2
- IGF2R | c.5833+2T>C p.X1945_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | catalogued as COSV63631461; called by muse, mutect2, varscan2
- IGFL2 | c.196T>C p.C66R (on ENST00000377693 / NM_001135113.2; = p.C77R on NM_001002915.2) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66617274; called by muse, mutect2, varscan2
- IGHV6-1 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555405745; called by muse, mutect2, varscan2
- IGSF9B | c.3587T>C p.L1196P | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV58071040; called by muse, mutect2, varscan2
- IGSF9B | c.2096A>T p.N699I | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58071050; called by muse, mutect2, varscan2
- IL12RB1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV74045638; called by muse, mutect2, varscan2
- IL18R1 | c.1472T>C p.L491P | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52126296; called by muse, mutect2, varscan2
- IL4R | c.1153T>G p.C385G | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV99404555; called by muse, mutect2, varscan2
- ILDR1 | c.413G>A p.W138* | Nonsense Mutation (SNP) | VAF 59/136 reads (43%) | catalogued as COSV56552285; called by muse, varscan2
- ILF2 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as COSV62627884; called by muse, mutect2, varscan2
- IMPDH2 | c.989T>C p.I330T | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58708671; called by muse, mutect2, varscan2
- IMPG1 | c.28T>A p.F10I | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as COSV64060259; called by muse, varscan2
- INHA | c.782A>T p.N261I | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV54726867; called by muse, mutect2, varscan2
- INTS13 | c.1478A>G p.N493S | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.138); catalogued as COSV53904469; called by muse, mutect2, varscan2
- INTS5 | c.2909T>G p.I970S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs771890989, COSV57952937; called by muse, mutect2, varscan2
- INTS6 | c.2346A>T p.Q782H | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.396); catalogued as COSV60879702; called by muse, mutect2, varscan2
- INTS7 | c.2345T>C p.I782T | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.985); catalogued as COSV65344937; called by muse, mutect2, varscan2
- IPO7 | c.2474T>C p.V825A | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as COSV65686378; called by muse, varscan2
- IQGAP2 | c.470T>C p.F157S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57178533; called by muse, mutect2, varscan2
- IRS1 | c.1463G>T p.G488V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as rs1012124430, COSV100523752; called by muse, mutect2
- ITFG1 | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV57753205; called by muse, mutect2, varscan2
- ITFG1 | c.1037A>G p.D346G | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV57753212; called by muse, mutect2, varscan2
- ITGB6 | c.1753T>C p.S585P | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV51797152; called by muse, mutect2, varscan2
- JAK1 | c.1685A>G p.Q562R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.045); catalogued as COSV61094736; called by muse, mutect2, varscan2
- JDP2 | c.331A>C p.N111H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99966527; called by muse, mutect2
- JMJD1C | c.6075dup p.E2026Rfs*8 | Frame Shift Ins (INS) | VAF 68/148 reads (46%) | catalogued as rs1226801045; called by mutect2, varscan2
- KAT6A | c.1482+2T>C p.X494_splice | Splice Site (SNP) | VAF 29/96 reads (30%) | catalogued as COSV55910148; called by muse, mutect2, varscan2
- KATNIP | c.2593A>G p.S865G | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55188200; called by muse, mutect2, varscan2
- KCNA6 | c.1028T>C p.V343A | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54976761; called by muse, mutect2, varscan2
- KCND2 | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV58595581; called by muse, mutect2, varscan2
- KCNH8 | c.97A>G p.N33D | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60472005; called by muse, mutect2, varscan2
- KCNJ12 | c.948C>A p.Y316* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV59171301, COSV59175078; called by muse, mutect2, varscan2
- KCNJ4 | c.1256T>C p.F419S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as COSV57858156; called by muse, mutect2, varscan2
- KCNK18 | c.964A>G p.T322A | Missense Mutation (SNP) | VAF 132/274 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57972674; called by muse, mutect2, varscan2
- KCNRG | c.508A>G p.R170G | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53950820; called by muse, mutect2, varscan2
- KCNT2 | c.2324A>G p.Y775C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1156808090, COSV54098410; called by muse, mutect2, varscan2
- KCTD19 | c.1763A>G p.Y588C | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV58574262; called by muse, mutect2, varscan2
- KDM1A | c.1361A>G p.K454R | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV63089373; called by muse, mutect2, varscan2
- KIAA0232 | c.231+1G>A p.X77_splice | Splice Site (SNP) | VAF 29/67 reads (43%) | catalogued as COSV56927794; called by muse, mutect2, varscan2
- KIAA0319 | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV65501033; called by muse, mutect2, varscan2
- KIAA0319L | c.2303A>G p.D768G | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57848855; called by muse, mutect2, varscan2
- KIAA1217 | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1161357730, COSV56820971; called by muse, mutect2, varscan2
- KIAA1841 | c.1531T>C p.C511R | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV54377550; called by muse, mutect2, varscan2
- KIDINS220 | c.3011G>A p.R1004K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.757); catalogued as COSV56757287; called by muse, mutect2, varscan2
- KIDINS220 | c.2551A>G p.N851D | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.155); catalogued as rs1421638048, COSV99874663; called by muse, mutect2
- KIF11 | c.2110T>G p.C704G | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.206); catalogued as COSV53270675, COSV99585543; called by muse, mutect2
- KIF14 | c.3266A>G p.K1089R | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV66263235; called by muse, mutect2, varscan2
- KIF1B | c.1958C>A p.P653H (on ENST00000377086 / NM_001365952.1; = p.P607H on NM_015074.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99822153, COSV99822475; called by muse, mutect2
- KIF1C | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.726); catalogued as COSV57906068; called by muse, varscan2
- KIF2A | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1258484187, COSV66946291; called by muse, mutect2, varscan2
- KIF3A | c.1372C>A p.L458I | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV66415845; called by muse, mutect2, varscan2
- KIF3B | c.1319T>C p.M440T | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV65228764; called by muse, varscan2
- KIF5B | c.1865T>C p.M622T | Missense Mutation (SNP) | VAF 118/261 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV56654916; called by muse, mutect2, varscan2
- KLHL1 | c.1208T>C p.L403P | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64778366; called by muse, mutect2, varscan2
- KLHL2 | c.643T>G p.S215A | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV56980881; called by muse, mutect2, varscan2
- KLKB1 | c.1018T>G p.C340G | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52997821; called by muse, mutect2, varscan2
- KMT2A | c.2915C>A p.T972N | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs782663858, COSV63287169; called by muse, mutect2, varscan2
- KMT2D | c.11314A>G p.K3772E | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as COSV56470665; called by muse, mutect2, varscan2
- KMT2E | c.3962T>G p.L1321R | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.07); catalogued as COSV57577509; called by muse, mutect2, varscan2
- KNTC1 | c.6410A>G p.E2137G | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV61082701; called by muse, mutect2, varscan2
- KPNB1 | c.2104-2A>G p.X702_splice | Splice Site (SNP) | VAF 53/135 reads (39%) | catalogued as COSV51599313; called by muse, mutect2, varscan2
- KRIT1 | c.1225A>G p.K409E | Missense Mutation (SNP) | VAF 145/320 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV60669734; called by muse, mutect2, varscan2
- KRT23 | c.866A>G p.E289G | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52928679; called by muse, mutect2, varscan2
- KRT25 | c.479A>C p.N160T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56446029; called by muse, mutect2, varscan2
- KRT26 | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59415314; called by muse, mutect2, varscan2
- KRT33A | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50371630; called by muse, mutect2, varscan2
- KRT75 | c.1038C>T p.Y346= | Splice Region (SNP) | VAF 60/119 reads (50%) | catalogued as rs775370881, COSV52874403; called by muse, mutect2, varscan2
- KRT77 | c.41T>C p.M14T | Missense Mutation (SNP) | VAF 77/142 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs371763767; called by muse, mutect2, varscan2
- KRTAP10-7 | c.418A>G p.S140G | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV59110694; called by muse, mutect2, varscan2
- KRTAP5-11 | c.456C>A p.C152* | Nonsense Mutation (SNP) | VAF 73/159 reads (46%) | catalogued as rs759879477, COSV59371233; called by muse, mutect2, varscan2
- KRTAP5-6 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.367); catalogued as COSV66289322; called by muse, mutect2, varscan2
- KRTAP5-9 | c.49T>G p.C17G | Missense Mutation (SNP) | VAF 45/92 reads (49%) | PolyPhen possibly damaging (0.683); catalogued as COSV73200246; called by muse, mutect2, varscan2
- KSR2 | c.1970A>G p.Q657R | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.273); catalogued as COSV56679685; called by muse, mutect2, varscan2
- KTN1 | c.2360A>C p.N787T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV63215742; called by muse, mutect2, varscan2
- KTN1 | c.3832A>G p.K1278E (on ENST00000395314 / NM_001271014.2; = p.K1221E on NM_004986.4) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58540847; called by muse, mutect2, varscan2
- KYAT3 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775283096, COSV53104159; called by muse, varscan2
- KYNU | c.329T>A p.I110N | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV51588736; called by muse, mutect2, varscan2
- L1CAM | c.1988A>G p.Y663C | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.432); catalogued as COSV62829459; called by muse, mutect2, varscan2
- LAMA1 | c.5067T>G p.N1689K | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.306); catalogued as COSV67541523; called by muse, mutect2, varscan2
- LAMB2 | c.5000T>C p.L1667P | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV59736305; called by muse, varscan2
- LAMC1 | c.1987A>G p.R663G | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV51161010; called by muse, varscan2
- LARP1 | c.437-2A>G p.X146_splice (on ENST00000518297 / NM_033551.3; = p.X69_splice on NM_015315.5 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 30/84 reads (36%) | catalogued as COSV60429961; called by muse, mutect2, varscan2
- LARP4 | c.1420A>G p.T474A | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV53325508; called by muse, mutect2, varscan2
- LARS1 | c.3439T>C p.F1147L (on ENST00000394434 / NM_020117.11; = p.F1120L on NM_016460.3) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV50983871; called by muse, mutect2, varscan2
- LAT2 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV51922184; called by muse, mutect2, varscan2
- LBP | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as COSV54142337; called by muse, mutect2, varscan2
- LCA5 | c.953dup p.N318Kfs*7 | Frame Shift Ins (INS) | VAF 47/125 reads (38%) | catalogued as rs1429753961; called by mutect2, pindel, varscan2
- LCOR | c.3530A>G p.N1177S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.121); catalogued as COSV53717644; called by muse, varscan2
- LDHAL6A | c.788T>G p.I263S | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52651980; called by muse, mutect2, varscan2
- LEMD2 | c.1087A>G p.M363V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53394856; called by muse, mutect2, varscan2
- LGR5 | c.1461T>A p.N487K | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as COSV57008190; called by muse, mutect2, varscan2
- LILRB4 | c.945G>T p.Q315H | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV54407519, COSV99553622; called by muse, mutect2, varscan2
- LIN28B | c.728C>G p.S243* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs1192629337, COSV61496717; called by muse, mutect2, varscan2
- LIN7C | c.564G>T p.M188I | Missense Mutation (SNP) | VAF 88/230 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53416252; called by muse, mutect2, varscan2
- LITAF | c.454A>G p.R152G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV59656664; called by muse, mutect2
- LMBRD2 | c.989T>G p.L330R | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56951743; called by muse, mutect2, varscan2
- LMNB1 | c.1558T>C p.S520P | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV54399234; called by muse, mutect2, varscan2
- LNX2 | c.540T>A p.C180* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV60337529; called by muse, mutect2, varscan2
- LONP2 | c.1153G>T p.G385* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as COSV53524601; called by muse, mutect2, varscan2
- LPCAT3 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV54646829; called by muse, mutect2, varscan2
- LPIN1 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56768725; called by muse, mutect2, varscan2
- LPL | c.913T>C p.C305R | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs773235712, CM043863, COSV60932308; called by muse, mutect2, varscan2
- LPL | c.1193A>G p.D398G | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60932315; called by muse, mutect2, varscan2
- LRAT | c.554T>C p.V185A | Missense Mutation (SNP) | VAF 139/330 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV60477779; called by muse, mutect2, varscan2
- LRFN2 | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.01); catalogued as COSV57832015, COSV57832185; called by muse, mutect2, varscan2
- LRP2 | c.13601A>C p.K4534T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs757334722, COSV55566502; called by muse, mutect2, varscan2
- LRP2 | c.10364A>G p.H3455R | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV55566514; called by muse, mutect2, varscan2
- LRRC31 | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV52982186; called by muse, mutect2, varscan2
- LRRC3B | c.527T>A p.V176E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV67522108; called by muse, mutect2, varscan2
- LRRC43 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60291939; called by muse, mutect2, varscan2
- LRRFIP1 | c.1916A>G p.Q639R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV57831374; called by muse, mutect2, varscan2
- LRRK2 | c.626T>C p.L209S | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54163978; called by muse, mutect2, varscan2
- LUC7L3 | c.544T>A p.F182I | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as COSV53588567; called by muse, mutect2, varscan2
- LYZL1 | c.166A>G p.I56V (on ENST00000375500; = p.I10V on NM_032517.6) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs754886597, COSV64966775; called by muse, mutect2, varscan2
- MACF1 | c.7822C>A p.L2608M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV57135387; called by muse, mutect2, varscan2
- MACF1 | c.14306A>G p.K4769R (on ENST00000372915; = p.K2702R on NM_012090.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV57135406; called by muse, mutect2, varscan2
- MACROH2A1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV56897192; called by muse, mutect2, varscan2
- MADD | c.1141T>C p.F381L | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60628105; called by muse, mutect2, varscan2
- MAGI3 | c.1623T>A p.N541K | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.341); catalogued as COSV56841576; called by muse, mutect2, varscan2
- MAN1A1 | c.611A>G p.K204R | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.392); catalogued as COSV63783931; called by muse, mutect2, varscan2
- MAP1LC3A | c.158T>C p.L53S | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54165068; called by muse, mutect2, varscan2
- MAP3K20 | c.352A>C p.M118L | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.305); catalogued as COSV59105222; called by muse, mutect2, varscan2
- MAP3K7 | c.1177T>C p.S393P | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV65225478; called by muse, mutect2, varscan2
- MAP7D3 | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 205/494 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60171984; called by muse, mutect2, varscan2
- MAPKAPK5 | c.1392A>C p.E464D (on ENST00000551404 / NM_139078.3; = p.E462D on NM_003668.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV73436119; called by muse, mutect2, varscan2
- MARK2 | c.288+2T>A p.X96_splice | Splice Site (SNP) | VAF 64/135 reads (47%) | catalogued as COSV59286884; called by muse, mutect2, varscan2
- MASTL | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776845402, COSV60909748; called by muse, varscan2
- MATN2 | c.1440G>T p.K480N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54716649; called by muse, mutect2, varscan2
- MB21D2 | c.701A>G p.D234G | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66665216; called by muse, mutect2, varscan2
- MBNL1 | c.896A>G p.K299R (on ENST00000282486 / NM_207293.2; = p.K281R on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56833232; called by muse, mutect2, varscan2
- MBOAT1 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV61126920; called by muse, mutect2, varscan2
- MBOAT7 | c.976T>C p.W326R | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778806571, COSV55477076; called by muse, mutect2, varscan2
- MCCC1 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV55610696; called by muse, mutect2, varscan2
- MDFIC | c.301A>C p.T101P | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV57566212; called by muse, mutect2, varscan2
- MDM2 | c.1154A>G p.D385G | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV50701639; called by muse, varscan2
- MDN1 | c.13702A>G p.T4568A | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV65527173; called by muse, mutect2, varscan2
- MED13L | c.5321T>C p.F1774S | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56126414; called by muse, mutect2, varscan2
- MED17 | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV52602418; called by muse, mutect2, varscan2
- MED28 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.135); catalogued as rs1175528950, COSV52847018; called by muse, mutect2, varscan2
- MED30 | c.252A>T p.Q84H | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV52068096; called by muse, mutect2, varscan2
- MEGF6 | c.4563A>C p.S1521= | Splice Region (SNP) | VAF 34/60 reads (57%) | catalogued as rs752556317, COSV53893533; called by muse, mutect2, varscan2
- MEGF8 | c.362A>G p.H121R | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV52095874; called by muse, mutect2, varscan2
- METTL17 | c.613A>C p.S205R | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59556733; called by muse, mutect2, varscan2
- MFSD10 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780693139, COSV53272382; called by muse, mutect2, varscan2
- MFSD4A | c.797A>G p.E266G | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV65656866; called by muse, mutect2, varscan2
- MGAT5 | c.1892T>C p.M631T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.546); catalogued as rs1380927985, COSV56099581; called by muse, mutect2, varscan2
- MICAL2 | c.1450-2A>C p.X484_splice | Splice Site (SNP) | VAF 29/62 reads (47%) | catalogued as COSV56323773; called by muse, mutect2, varscan2
- MICAL3 | c.435C>A p.F145L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52902595; called by muse, mutect2, varscan2
- MIER2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as rs201514181, COSV53397424, COSV99316091; called by muse, mutect2, varscan2
- MINAR1 | c.911T>G p.F304C | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59585321; called by muse, mutect2, varscan2
- MKI67 | c.8446A>G p.T2816A | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.103); catalogued as COSV64075861; called by muse, mutect2, varscan2
- MLH3 | c.3426C>A p.F1142L | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV53152254; called by muse, mutect2, varscan2
- MLIP | c.911C>A p.P304Q | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.285); catalogued as COSV51434416; called by muse, mutect2, varscan2
- MMP10 | c.776A>G p.Q259R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54247121; called by muse, varscan2
- MMP14 | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV61289072; called by muse, mutect2, varscan2
- MMP27 | c.760A>G p.N254D | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52782040; called by muse, mutect2, varscan2
- MMS22L | c.3197A>G p.K1066R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99245807; called by muse, mutect2, varscan2
- MN1 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV56560756; called by muse, mutect2, varscan2
- MOCOS | c.1853T>C p.V618A | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV54345851; called by muse, mutect2, varscan2
- MON1A | c.1422C>A p.F474L | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56562010; called by muse, mutect2, varscan2
- MORF4L2 | c.91A>G p.R31G | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV64611283; called by muse, mutect2, varscan2
- MOV10 | c.934A>C p.S312R | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV62492213; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2202A>G p.I734M | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64056950; called by muse, mutect2, varscan2
- MPP2 | c.860A>T p.N287I (on ENST00000461854 / NM_001278372.2; = p.N263I on NM_005374.5) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52238579; called by muse, mutect2, varscan2
- MPRIP | c.2318A>G p.E773G | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV57929363; called by muse, mutect2, varscan2
- MPZL3 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778832557, COSV54053754; called by muse, mutect2, varscan2
- MRC2 | c.2306A>G p.Y769C | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57642820; called by muse, mutect2, varscan2
- MRTFB | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57960193; called by muse, mutect2, varscan2
- MS4A10 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57633389; called by muse, mutect2, varscan2
- MSLNL | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.044); catalogued as rs757451139, COSV53504813; called by muse, mutect2, varscan2
- MSN | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.378); catalogued as COSV64305035; called by muse, mutect2, varscan2
- MSX2 | c.659T>C p.F220S | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53327943; called by muse, mutect2, varscan2
- MTCH1 | c.967A>G p.M323V (on ENST00000373627 / NM_001271641.1; = p.M306V on NM_014341.2) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV65321188; called by muse, mutect2, varscan2
- MTHFD1L | c.2827A>G p.I943V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV66226694; called by muse, mutect2, varscan2
- MTIF3 | c.497A>C p.N166T | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as COSV63528700; called by muse, mutect2, varscan2
- MUC16 | c.42458T>C p.V14153A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.78); PolyPhen probably damaging (0.91); catalogued as COSV66695164; called by muse, mutect2, varscan2
1,233 further variants in this file (726 protein-altering or splice-affecting, 481 silent, 26 other) are not listed here.
